Somatic mutation profile of tumor specimen TCGA-AU-3779-01A (aliquot TCGA-AU-3779-01A-01D-1719-10) from TCGA case TCGA-AU-3779, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 80.7 years (29,460 days).
Specimen TCGA-AU-3779-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 91272edb-617e-49aa-b281-4dd030ad6fde.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AU-3779-10A (Blood Derived Normal), aliquot TCGA-AU-3779-10A-01D-1719-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/be6be1f9-4c8f-446f-9728-c1509a16befa

The open-access MAF lists 114 somatic variants for this specimen: 84 protein-altering or splice-affecting, 26 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 75, Silent 26, Nonsense Mutation 6, RNA 2, Splice Region 2, Intron 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 41/74 reads (55%) | hotspot (GDC flag); catalogued as rs587781392, CM920027, COSV57321978; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 38/64 reads (59%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- ACTRT1 | c.112G>A p.V38I | Missense Mutation (SNP) | VAF 60/333 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs138725538, COSV64418994; called by muse, mutect2, varscan2
- ADCY2 | c.2813T>C p.I938T | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57861105; called by muse, mutect2, varscan2
- ALOX5 | c.1334C>T p.T445I | Missense Mutation (SNP) | VAF 45/74 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1424670795, COSV65551317; called by muse, mutect2, varscan2
- AMPH | c.128T>C p.V43A | Missense Mutation (SNP) | VAF 93/891 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV57734825; called by muse, mutect2, varscan2
- ANKRD30A | c.2560G>A p.V854I (on ENST00000611781; = p.V798I on NM_052997.2) | Missense Mutation (SNP) | VAF 95/388 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.027); catalogued as rs749191300, COSV64605479; called by muse, mutect2, varscan2
- APC | c.4031C>A p.S1344* | Nonsense Mutation (SNP) | VAF 27/143 reads (19%) | catalogued as CM058101, COSV57323283, COSV57323895, COSV57365719; called by muse, mutect2, varscan2
- ASIC5 | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 60/139 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as rs752632438, COSV73332561, COSV73332754; called by muse, mutect2, varscan2
- ASPG | c.1237G>A p.D413N | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.059); catalogued as rs756096595, COSV71933596; called by muse, mutect2, varscan2
- ATP2B3 | c.2221C>T p.R741C | Missense Mutation (SNP) | VAF 175/488 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.209); catalogued as rs1215901845, COSV54841395; called by muse, mutect2, varscan2
- BAG2 | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 32/104 reads (31%) | catalogued as COSV65786662; called by muse, mutect2, varscan2
- BCAS3 | c.2561C>T p.T854M (on ENST00000390652 / NM_001353144.2; = p.T839M on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.548); catalogued as rs545072054, COSV66770581; called by muse, mutect2, varscan2
- BPIFB6 | c.600G>T p.M200I | Missense Mutation (SNP) | VAF 162/351 reads (46%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs1360198467, COSV62754431; called by muse, mutect2, varscan2
- CABP5 | c.316G>A p.G106S | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.97); catalogued as rs200158927, COSV53152119, COSV99506655; called by muse, mutect2, varscan2
- CFAP47 | c.4864A>C p.K1622Q | Missense Mutation (SNP) | VAF 63/206 reads (31%) | SIFT tolerated, low confidence (0.44); PolyPhen probably damaging (0.925); catalogued as COSV57971692; called by muse, mutect2, varscan2
- CLEC2B | c.434G>A p.R145K | Missense Mutation (SNP) | VAF 64/275 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.115); catalogued as rs947154216, COSV99946902; called by muse, mutect2, varscan2
- CLEC4C | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 67/161 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.28); catalogued as rs747788810, COSV63582305, COSV63582674; called by muse, mutect2, varscan2
- CSMD1 | c.10063G>A p.V3355I (on ENST00000520002; = p.V3354I on NM_033225.6) | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs202012312; called by muse, mutect2
- CWF19L1 | c.1196G>A p.R399Q | Missense Mutation (SNP) | VAF 29/262 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs749733351, COSV62498992; called by muse, mutect2, varscan2
- CYB5RL | c.900G>T p.R300S | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV55276717; called by muse, mutect2, varscan2
- DNAH10 | c.8210C>T p.T2737M (on ENST00000409039; = p.T2676M on NM_207437.3) | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs756405690, COSV68989039; called by muse, mutect2, varscan2
- DNAH17 | c.12915G>A p.R4305= | Splice Region (SNP) | VAF 16/54 reads (30%) | catalogued as COSV53143682; called by muse, mutect2, varscan2
- DNAH5 | c.4613C>T p.A1538V | Missense Mutation (SNP) | VAF 48/232 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201165908, COSV99444675, COSV99448650; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH8 | c.6845G>A p.R2282H | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs1253356713, COSV59478663; called by muse, mutect2, varscan2
- DTNA | c.1816G>A p.A606T | Missense Mutation (SNP) | VAF 34/259 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.687); catalogued as COSV51992994; called by muse, mutect2, varscan2
- FOXD2 | c.1391C>T p.A464V | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.212); catalogued as rs1331340766, COSV58303611; called by muse, varscan2
- FOXF1 | c.524C>T p.S175L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as rs1344184347, COSV99296315; called by muse, mutect2, varscan2
- GC | c.761T>A p.L254Q | Missense Mutation (SNP) | VAF 77/126 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56735666; called by muse, mutect2, varscan2
- GPR37 | c.1364C>T p.T455M | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.769); catalogued as rs774806947, COSV58259643; called by muse, mutect2, varscan2
- HEG1 | c.1547C>T p.S516L | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as rs765727595, COSV60759893; called by muse, mutect2, varscan2
- HFM1 | c.2231A>G p.D744G | Missense Mutation (SNP) | VAF 96/349 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.085); catalogued as COSV54022580; called by muse, mutect2, varscan2
- HTATSF1 | c.106G>A p.G36R | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV54477602; called by muse, mutect2, varscan2
- IRS4 | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 130/304 reads (43%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.426); catalogued as COSV100929414; called by muse, mutect2, varscan2
- KCNH7 | c.1268T>A p.I423K | Missense Mutation (SNP) | VAF 55/222 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV59787966; called by muse, mutect2, varscan2
- KMT2C | c.4197G>A p.M1399I | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV100066377; called by muse, mutect2, varscan2
- LETM1 | c.332C>T p.S111L | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.485); catalogued as rs1461897001, COSV100245190, COSV57100117; called by muse, mutect2, varscan2
- LIMD1 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV56266098, COSV99837036; called by muse, mutect2, varscan2
- LRRC4B | c.1157G>A p.R386H | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV65349185; called by muse, mutect2, varscan2
- LRRTM1 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 57/255 reads (22%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.817); catalogued as COSV54438776; called by muse, mutect2, varscan2
- LRRTM2 | c.943T>G p.C315G | Missense Mutation (SNP) | VAF 74/181 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51220090; called by muse, mutect2
- LRRTM2 | c.941A>T p.E314V | Missense Mutation (SNP) | VAF 74/177 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV51220108; called by muse, mutect2
- LTA4H | c.1228G>A p.A410T | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.194); catalogued as COSV57381809; called by muse, mutect2, varscan2
- MAGEC3 | c.1516G>T p.E506* | Nonsense Mutation (SNP) | VAF 38/266 reads (14%) | catalogued as COSV53576884; called by muse, mutect2, varscan2
- MAPK8 | c.112G>C p.G38R | Missense Mutation (SNP) | VAF 120/225 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64408343, COSV64408480; called by muse, mutect2, varscan2
- MBD3L1 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV59775751; called by muse, mutect2, varscan2
- MPP1 | c.1007C>T p.T336M | Missense Mutation (SNP) | VAF 110/570 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); catalogued as rs373323050, COSV65729216; called by muse, mutect2, varscan2
- MPP2 | c.946C>T p.R316W (on ENST00000461854 / NM_001278372.2; = p.R292W on NM_005374.5) | Missense Mutation (SNP) | VAF 55/240 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770872796, COSV52233452; called by muse, mutect2, varscan2
- NAP1L3 | c.262C>T p.R88W | Missense Mutation (SNP) | VAF 17/177 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1163788167, COSV59073966; called by muse, mutect2
- NEU3 | c.301G>A p.V101I | Missense Mutation (SNP) | VAF 71/130 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as COSV53635815; called by muse, mutect2, varscan2
- NLRP3 | c.1789A>C p.K597Q | Missense Mutation (SNP) | VAF 42/165 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as COSV60220937; called by muse, mutect2, varscan2
- NPAS3 | c.1450G>A p.D484N (on ENST00000356141 / NM_001164749.2; = p.D452N on NM_022123.3) | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT tolerated (0.21); PolyPhen benign (0.075); catalogued as rs756991498, COSV60823823; called by muse, mutect2, varscan2
- NUP188 | c.4512C>T p.N1504= | Splice Region (SNP) | VAF 78/125 reads (62%) | catalogued as COSV65330274; called by muse, mutect2, varscan2
- OGT | c.823A>G p.I275V | Missense Mutation (SNP) | VAF 40/203 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as COSV101035151; called by muse, mutect2, varscan2
- OR5W2 | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 101/160 reads (63%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.466); catalogued as rs750353731, COSV60614549, COSV60616410; called by muse, mutect2, varscan2
- PBX2 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66708720; called by muse, varscan2
- POU4F2 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 89/118 reads (75%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV55583115; called by muse, mutect2, varscan2
- PTGS2 | c.1747T>C p.S583P | Missense Mutation (SNP) | VAF 54/292 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV100821664; called by muse, varscan2
- PTPRT | c.2750G>T p.R917L | Missense Mutation (SNP) | VAF 228/642 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as COSV61964248, COSV61973369; called by muse, mutect2, varscan2
- RIMS2 | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 47/240 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs762621849, COSV68471032; called by muse, mutect2, varscan2
- SCN2A | c.1711C>T p.R571C | Missense Mutation (SNP) | VAF 86/196 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750049844, COSV51834008; called by muse, mutect2, varscan2
- SERPINI2 | c.973G>T p.E325* | Nonsense Mutation (SNP) | VAF 106/221 reads (48%) | catalogued as COSV52984403, COSV99247526; called by muse, mutect2, varscan2
- SLITRK1 | c.1310C>A p.T437K | Missense Mutation (SNP) | VAF 83/199 reads (42%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV65674062, COSV65674512; called by muse, mutect2, varscan2
- SMARCA1 | c.2716T>C p.C906R | Missense Mutation (SNP) | VAF 84/512 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.805); catalogued as COSV64411060; called by muse, mutect2, varscan2
- SMARCA1 | c.794G>T p.G265V | Missense Mutation (SNP) | VAF 61/354 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755281078, COSV64411067; called by muse, mutect2, varscan2
- STAC | c.742G>T p.D248Y | Missense Mutation (SNP) | VAF 81/144 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as COSV56207388; called by muse, mutect2, varscan2
- STAT3 | c.1465-2A>C p.X489_splice | Splice Site (SNP) | VAF 26/110 reads (24%) | catalogued as COSV52884573; called by muse, mutect2, varscan2
- SUGP1 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.366); catalogued as rs759906189, COSV99894523; called by muse, mutect2, varscan2
- TM9SF2 | c.1436G>A p.C479Y | Missense Mutation (SNP) | VAF 54/366 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV64506303; called by muse, mutect2, varscan2
- TNKS2 | c.1399T>G p.F467V | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.038); catalogued as COSV65414837; called by muse, mutect2, varscan2
- TPST2 | c.94C>T p.R32W | Missense Mutation (SNP) | VAF 24/31 reads (77%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.116); catalogued as rs745617634, COSV58678538; called by muse, mutect2, varscan2
- TSPYL2 | c.716G>A p.R239H | Missense Mutation (SNP) | VAF 134/748 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV60233694; called by muse, mutect2, varscan2
- TTN | c.1541G>T p.R514I | Missense Mutation (SNP) | VAF 30/187 reads (16%) | PolyPhen probably damaging (0.983); catalogued as rs139178471, COSV59914412; called by muse, mutect2, varscan2
- UBXN6 | c.475A>T p.M159L | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.034); catalogued as COSV56670624; called by muse, mutect2, varscan2
- UHRF1BP1 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 43/186 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.036); catalogued as rs377703789, COSV51953141; called by muse, mutect2, varscan2
- USP32 | c.621G>C p.K207N | Missense Mutation (SNP) | VAF 89/223 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56265034; called by muse, mutect2, varscan2
- VCAN | c.10013G>A p.R3338Q | Missense Mutation (SNP) | VAF 53/212 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754880024, COSV54098444; called by muse, mutect2, varscan2
- VCL | c.91G>T p.E31* | Nonsense Mutation (SNP) | VAF 18/107 reads (17%) | catalogued as COSV99280397; called by muse, mutect2, varscan2
- VPS13C | c.3713G>A p.R1238H (on ENST00000644861 / NM_020821.3; = p.R1195H on NM_017684.5) | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs139602306; called by muse, mutect2, varscan2
- WNT5B | c.824C>T p.P275L | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.046); catalogued as rs771391653, COSV60197501; called by muse, mutect2, varscan2
- YTHDC2 | c.3953G>A p.R1318Q | Missense Mutation (SNP) | VAF 49/240 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1345338539, COSV50737104; called by muse, mutect2, varscan2
- ZFHX4 | c.8119T>A p.Y2707N | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV50549181; called by muse, mutect2, varscan2
- ZFP14 | c.1501A>T p.I501F | Missense Mutation (SNP) | VAF 28/199 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV54201294; called by muse, mutect2, varscan2
- IGHV3-66 | c.187G>A p.G63R | Missense Mutation (SNP) | VAF 70/136 reads (51%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- AC131160.1 | c.96C>T p.V32= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV100226072; called by muse, mutect2, varscan2
- BRD3 | c.543C>T p.T181= | Silent (SNP) | VAF 24/77 reads (31%) | catalogued as COSV57701624; called by muse, mutect2, varscan2
- C7orf25 | c.480T>C p.Y160= | Silent (SNP) | VAF 72/419 reads (17%) | catalogued as COSV63273223; called by muse, mutect2, varscan2
- CAMKV | c.54G>A p.S18= | Silent (SNP) | VAF 51/198 reads (26%) | catalogued as rs149864872, COSV56554044; called by muse, mutect2, varscan2
- CARD11 | c.501G>A p.T167= | Silent (SNP) | VAF 74/518 reads (14%) | catalogued as rs757881829, COSV62716578; called by muse, mutect2, varscan2
- CRACDL | c.1098C>T p.P366= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as COSV67406781; called by muse, mutect2, varscan2
- DYDC2 | c.363C>T p.F121= | Silent (SNP) | VAF 67/131 reads (51%) | catalogued as rs1393335448, COSV55472756; called by muse, mutect2, varscan2
- FBXO40 | c.1134G>T p.V378= | Silent (SNP) | VAF 48/183 reads (26%) | catalogued as COSV57522334; called by muse, mutect2, varscan2
- GJA9 | c.834C>T p.L278= | Silent (SNP) | VAF 105/423 reads (25%) | catalogued as COSV62531840; called by muse, mutect2, varscan2
- KCNJ15 | c.351G>A p.A117= | Silent (SNP) | VAF 18/104 reads (17%) | catalogued as rs150956930; called by muse, mutect2, varscan2
- KCNMB1 | c.357C>T p.D119= | Silent (SNP) | VAF 37/101 reads (37%) | catalogued as rs772278093, COSV51131148; called by muse, mutect2, varscan2
- MYO1D | c.120G>A p.T40= | Silent (SNP) | VAF 46/140 reads (33%) | catalogued as rs781163176, COSV59008275; called by muse, mutect2, varscan2
- OR5D16 | c.414C>A p.I138= | Silent (SNP) | VAF 120/201 reads (60%) | catalogued as rs747455484, COSV65721333; called by muse, mutect2, varscan2
- PCDHB10 | c.1965C>T p.T655= | Silent (SNP) | VAF 31/60 reads (52%) | catalogued as COSV53379369; called by muse, mutect2, varscan2
- PHC2 | c.63C>T p.S21= | Silent (SNP) | VAF 54/167 reads (32%) | catalogued as rs779187053, COSV57102200; called by muse, mutect2, varscan2
- PHF3 | c.4083T>C p.T1361= | Silent (SNP) | VAF 25/316 reads (8%) | catalogued as rs1392311247, COSV50314069; called by muse, mutect2
- PKHD1L1 | c.9771G>A p.L3257= | Silent (SNP) | VAF 62/319 reads (19%) | catalogued as rs749664514, COSV101005297; called by muse, mutect2, varscan2
- PKN3 | c.2130C>T p.I710= | Silent (SNP) | VAF 87/157 reads (55%) | catalogued as rs753510076, COSV52575181; called by muse, mutect2, varscan2
- POU3F4 | c.336C>T p.N112= | Silent (SNP) | VAF 103/535 reads (19%) | catalogued as rs1333994074, COSV64537768; called by muse, mutect2, varscan2
- PROZ | c.1119G>A p.S373= | Silent (SNP) | VAF 35/123 reads (28%) | catalogued as rs376192200; called by muse, mutect2, varscan2
- RAB39B | c.228C>T p.R76= | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as rs782369215, COSV65624286; called by muse, mutect2, varscan2
- SASH3 | c.699C>T p.P233= | Silent (SNP) | VAF 29/141 reads (21%) | catalogued as rs768262427, COSV63555672; called by muse, mutect2, varscan2
- SVIL | c.2367G>A p.K789= (on ENST00000355867 / NM_021738.3; = p.K363= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 49/331 reads (15%) | catalogued as COSV63440649; called by muse, mutect2, varscan2
- TRIM56 | c.1146C>T p.D382= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as rs756222969, COSV60157478; called by muse, mutect2, varscan2
- ZDHHC19 | c.300C>T p.H100= | Silent (SNP) | VAF 48/234 reads (21%) | catalogued as COSV56348206; called by muse, mutect2, varscan2
- ZNF205 | c.1134G>A p.T378= | Silent (SNP) | VAF 83/269 reads (31%) | catalogued as rs777151935, COSV54620056; called by muse, mutect2, varscan2
- CCNQP1 | n.451C>T | RNA (SNP) | VAF 44/208 reads (21%) | catalogued as rs777278030; called by muse, mutect2, varscan2
- CTBP2 | c.58+11727C>A | Intron (SNP) | VAF 22/79 reads (28%) | catalogued as COSV58339669; called by muse, mutect2, varscan2
- MIR514A3 | n.6C>A | RNA (SNP) | VAF 203/1294 reads (16%) | called by muse, mutect2, varscan2
- PTPRT | c.2983-740C>T | Intron (SNP) | VAF 41/122 reads (34%) | catalogued as rs768256114, COSV61987532; called by muse, mutect2, varscan2
